Surgical pathology report (de-identified scan), TCGA case TCGA-D7-6527, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-6527-01A (Primary Tumor).

Examination: Histopathological examination

Material: 1. Total organ resection – stomach

TCGA – D7 – 6527

Physician in charge:

Material collected on:

Material received on:

Expected time of examination

Clinical diagnosis: Cancer of the cardia.

Examination performed on:

Macroscopic description:

Sent material containing the stomach, incised along the greater curvature, sized 19.6 x 12.7 cm with the omentum sized 29 x 10 cm. Tumour sized 5.2 x 4.1 x 0.4 cm with an ulceration sized 4.6 x 3.8 found in the cardiac region on the lesser curvature. Distance from the proximal end 0.5 cm, from distal end 11.8 cm.

Microscopic description:

Adenocarcinoma tubulare (G2).

Infiltratio carcinomatosa profunda tunicae muscularis propriae ventriculi et partietis oesophagi.

Emboliae carcinomatosaе vasorum.

Margins of normal tissues as in the macroscopic description.

Incision lines free of neoplastic lesions

Outside tumour: Gastritic chronica (+++) non activa (+).

Metaplasia intestinalis (+++) completa.

LYMPH NODES:

- periorificial (L, N) - metastases carcinomatosaе in lymphonodo (No I/IV).

Infiltratio carcinomatosa capsulae lymphonodi.

- of lesser curvature (O, P) - lymphonodis reactiva No VIII.

- of greater curvature (R) - lymphonodis reactiva No I.

- peripyloric (S) - lymphonodis reactiva No I.

Histopathological diagnosis:

Adenocarcinoma papillare ventriculi: Papillar adenocarcinoma of the stomach

metastases in lymphonodo regionalio No I/XIV. Cancer metastases of the regional lymph nodes (No I/XIV)

Emboliae carcinomatosaе. Cancerous emboli

G2, pT2, pN1.

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 581d1d23-328f-499b-ad56-c434102d19c3 (TCGA-D7-6527.C2311FDA-D860-4C91-A3D7-0FB1402353D9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).